Somatic mutation profile of tumor specimen TCGA-EY-A214-01A (aliquot TCGA-EY-A214-01A-12D-A159-09) from TCGA case TCGA-EY-A214, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 66.1 years (24,136 days).
Specimen TCGA-EY-A214-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 305a2b32-92f9-438f-b547-76f0e84fcd5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A214-10A (Blood Derived Normal), aliquot TCGA-EY-A214-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c06522d0-7b0a-42d0-89a3-2dbb5ccc969d

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 38, Silent 16, Nonsense Mutation 5, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 41/59 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3132T>A p.N1044K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100597754; called by muse, mutect2, varscan2
- AKT3 | c.1164-2A>G p.X388_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99794638; called by muse, mutect2, varscan2
- ARID1A | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100249938, COSV61383854; called by muse, mutect2, varscan2
- BAGE2 | n.225T>A | Splice Region (SNP) | VAF 10/264 reads (4%) | catalogued as rs1396662648; called by muse, mutect2
- BHMT | c.483T>G p.F161L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV99165387; called by muse, mutect2, varscan2
- BMP1 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200401797; called by muse, mutect2, varscan2
- CALN1 | c.170C>G p.S57C (on ENST00000329008 / NM_001017440.3; = p.S99C on NM_031468.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100205773; called by muse, mutect2, varscan2
- COL28A1 | c.2872C>T p.H958Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs1400490929, COSV101258421; called by muse, mutect2, varscan2
- CRYGS | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs758973330, COSV57192125; called by muse, mutect2, varscan2
- CSMD3 | c.9644G>A p.C3215Y (on ENST00000297405 / NM_001363185.1; = p.C3046Y on NM_052900.3) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99828970; called by muse, mutect2
- CST4 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54150608, COSV99463081; called by muse, mutect2, varscan2
- CT83 | c.203A>C p.N68T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.625); catalogued as COSV100902530; called by muse, mutect2, varscan2
- CTR9 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100797291; called by muse, varscan2
- DSE | c.1922A>G p.Y641C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100528440; called by muse, mutect2, varscan2
- DYRK2 | c.1636G>T p.E546* (on ENST00000344096 / NM_006482.3; = p.E473* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100165233; called by muse, mutect2
- EML5 | c.1002T>A p.H334Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100715261; called by muse, mutect2, varscan2
- FSCN3 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.343); catalogued as rs752054637, COSV50002110, COSV99133667; called by muse, mutect2, varscan2
- HBS1L | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892526; called by muse, mutect2, varscan2
- HELQ | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99787509; called by muse, mutect2, varscan2
- KRT73 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV99988370; called by muse, mutect2, varscan2
- KRT79 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1170550788, COSV100398341; called by muse, mutect2, varscan2
- LRFN5 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99983014; called by muse, mutect2, varscan2
- LRP5 | c.3153C>G p.H1051Q | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99591637; called by muse, mutect2, varscan2
- OR52N4 | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760216833, COSV100421631; called by muse, mutect2, varscan2
- OR7A10 | c.852G>C p.M284I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.301); catalogued as COSV99932402; called by muse, mutect2, varscan2
- PCDH9 | c.3481T>A p.F1161I (on ENST00000377865 / NM_203487.3; = p.F1127I on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100119321, COSV60576969; called by muse, mutect2, varscan2
- PDE1C | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1477802969, COSV58506147, COSV58521029; called by muse, mutect2, varscan2
- PTPRT | c.2358G>T p.K786N | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100626095; called by muse, mutect2, varscan2
- RYR3 | c.5705A>T p.D1902V | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV101212249; called by muse, mutect2, varscan2
- SEMA4D | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs752715417, COSV100358099; called by muse, mutect2, varscan2
- SLC29A4 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as rs751640994, COSV99786698; called by muse, mutect2, varscan2
- SLC9A9 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100339966; called by muse, mutect2, varscan2
- SLITRK5 | c.917T>C p.L306S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100280528; called by muse, mutect2, varscan2
- SP4 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.093); catalogued as COSV99754224; called by muse, mutect2, varscan2
- STAC2 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs780080823, COSV100336305; called by muse, mutect2, varscan2
- TMEM82 | c.162T>A p.N54K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99606506; called by muse, mutect2, varscan2
- TMTC1 | c.547T>C p.Y183H (on ENST00000539277 / NM_001193451.2; = p.Y75H on NM_175861.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99759149; called by muse, mutect2, varscan2
- TNNT3 | c.605T>C p.L202P (on ENST00000397301 / NM_001367846.1; = p.L191P on NM_006757.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99548055; called by muse, mutect2, varscan2
- TP53I11 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100370845; called by muse, mutect2, varscan2
- UGT2A2 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV99684048; called by muse, mutect2, varscan2
- VSTM1 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs779173655, COSV100618711, COSV100618867; called by muse, mutect2, varscan2
- ZNF683 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV100853690; called by muse, mutect2, varscan2
- ACOT1 | c.240G>T p.L80= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100233395; called by muse, mutect2
- ADGRA2 | c.2535C>G p.S845= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99604809; called by muse, mutect2, varscan2
- AL645922.1 | c.609C>T p.L203= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100190894; called by muse, mutect2, varscan2
- BMP3 | c.1086G>A p.K362= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99261486; called by muse, mutect2, varscan2
- CASP8AP2 | c.1248T>C p.D416= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99386873; called by muse, mutect2
- DAB2 | c.1662T>A p.G554= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100297861; called by muse, mutect2, varscan2
- EPHA5 | c.300A>G p.Q100= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99897448; called by muse, mutect2, varscan2
- HCFC1 | c.723G>A p.T241= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1449522886, COSV100128663; called by muse, mutect2, varscan2
- HEPH | c.933G>A p.Q311= (on ENST00000343002; = p.Q44= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57961138; called by muse, mutect2, varscan2
- KIF3B | c.204G>A p.K68= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100996346; called by muse, mutect2
- OR10C1 | c.765C>T p.T255= (on ENST00000622521; = p.T253= on NM_013941.3) | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs776669312, COSV65824644; called by muse, mutect2
- PKHD1 | c.1123C>A p.R375= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as CM054804, COSV100582015; called by muse, mutect2, varscan2
- PLXNA4 | c.232C>T p.L78= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100323244; called by muse, mutect2, varscan2
- PSMD1 | c.87A>G p.A29= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100433432; called by muse, mutect2, varscan2
- SLCO5A1 | c.810G>A p.A270= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV52664229, COSV52668396; called by muse, mutect2
- SPTBN2 | c.3915C>G p.S1305= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100018607; called by muse, mutect2, varscan2
